Somatic mutation profile of tumor specimen 0DAXP5 from CCDI case PBBKMV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.8 years (2,483 days).
Specimen 0DAXP5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63e37fd8-1907-41c8-aec3-d0ddb9697d5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAXP2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/091b4ea7-3c36-4400-b0f3-9ec2fd6b0c85

The open-access MAF lists 11,850 somatic variants for this specimen: 7,415 protein-altering or splice-affecting, 2,516 silent, 1,919 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6,710, Silent 2,516, Intron 1,126, 3'UTR 452, Nonsense Mutation 359, 5'UTR 223, Splice Region 134, Splice Site 97, Frame Shift Del 80, 5'Flank 44, RNA 41, 3'Flank 33.

Variants (750 of 11,850; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.5527C>T p.R1843W | Missense Mutation (SNP) | VAF 204/796 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs62642576, CM990066; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 366/783 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs769569410, CM060776, COSV100216536; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC011455.2 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 37/536 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs201347156; ClinVar: likely pathogenic / not provided; called by muse, mutect2
- ACTG2 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 374/850 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.108); catalogued as rs869312168, COSV61828224; ClinVar: pathogenic; called by muse, varscan2
- ACTN2 | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 291/657 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs772909106, COSV63973777; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.7129C>T p.R2377* | Nonsense Mutation (SNP) | VAF 119/305 reads (39%) | catalogued as rs758718347, CM140447; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKRD11 | c.1801C>T p.R601* | Nonsense Mutation (SNP) | VAF 60/730 reads (8%) | catalogued as rs772229371, COSV56357972; ClinVar: pathogenic; called by muse, mutect2
- APC | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 153/554 reads (28%) | hotspot (GDC flag); catalogued as rs137854580, CM930023, COSV57322064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARSA | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 299/655 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs74315473, CM139390, CM940106, COSV53350851; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASS1 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 269/683 reads (39%) | catalogued as rs786204537, CM091427; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATL1 | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 212/471 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs864622269, CM043588; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATM | c.2921+1G>A p.X974_splice | Splice Site (SNP) | VAF 199/392 reads (51%) | catalogued as rs587781558, CS991304, COSV53740769, COSV53748775, COSV53767471; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AUTS2 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 107/280 reads (38%) | catalogued as rs1057517708, COSV100715246, COSV61435162; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.9097del p.T3033Lfs*29 | Frame Shift Del (DEL) | VAF 224/453 reads (49%) | catalogued as rs397507419; ClinVar: not provided / pathogenic; called by mutect2, varscan2
- CAPN3 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 46/736 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs863224956, CM129344, CM990311, COSV58826312; ClinVar: pathogenic; called by muse, mutect2
- CCDC40 | c.2712-1G>T p.X904_splice | Splice Site (SNP) | VAF 115/365 reads (32%) | catalogued as rs370706991, CS124817; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- CFAP44 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 84/358 reads (23%) | catalogued as rs866096259; ClinVar: pathogenic; called by muse, varscan2
- CHD7 | c.6148C>T p.R2050* | Nonsense Mutation (SNP) | VAF 200/480 reads (42%) | catalogued as rs886040996, CM060915; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHRNA4 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 290/665 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs281865068, CM094469, COSV64719406; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CLN6 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 265/492 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs769701646, CM1512132; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- COL6A2 | c.2627G>A p.R876H | Missense Mutation (SNP) | VAF 222/483 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1012567148, CM1312460, COSV52431403; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CYP4V2 | c.1199G>A p.R400H | Missense Mutation (SNP) | VAF 69/1034 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199476203, CM056577; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- DHX30 | c.2354G>A p.R785H (on ENST00000445061 / NM_138615.3; = p.R746H on NM_014966.3) | Missense Mutation (SNP) | VAF 311/716 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553706799; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYRK1B | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 287/668 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as rs367643250, CM145255; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EBF3 | c.934C>T p.R312* (on ENST00000355311 / NM_001375392.1; = p.R303* on NM_001005463.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 214/488 reads (44%) | catalogued as rs1064796669, COSV62475510; ClinVar: pathogenic; called by muse, varscan2
- GALNS | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 276/610 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs398123430, CM042061; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GFER | c.592G>A p.G198S | Missense Mutation (SNP) | VAF 244/560 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs147568500; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GLB1 | c.1769G>A p.R590H | Missense Mutation (SNP) | VAF 94/396 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398123351, CM930344, COSV100256995; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HGSNAT | c.493+1G>A p.X165_splice | Splice Site (SNP) | VAF 32/432 reads (7%) | catalogued as rs193066451, CS064420, COSV65533120; ClinVar: pathogenic; called by muse, mutect2
- KCNH2 | c.1888G>A p.V630I | Missense Mutation (SNP) | VAF 186/465 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as rs199472958, CM970804; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KIF1A | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 211/502 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs387906799, CM111829; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KLHL7 | c.1051C>T p.R351* (on ENST00000339077 / NM_001031710.3; = p.R303* on NM_018846.5) | Nonsense Mutation (SNP) | VAF 194/435 reads (45%) | catalogued as rs746612410, COSV59159623; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRIT1 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 157/394 reads (40%) | catalogued as rs866982998, CM1413284; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.5562+1G>A p.X1854_splice | Splice Site (SNP) | VAF 189/412 reads (46%) | catalogued as rs376014152; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LTBP2 | c.5446dup p.H1816Pfs*28 | Frame Shift Ins (INS) | VAF 129/562 reads (23%) | catalogued as rs777661862, COSV56208604; ClinVar: pathogenic; called by mutect2, varscan2
- MPDZ | c.4906C>T p.R1636* | Nonsense Mutation (SNP) | VAF 235/530 reads (44%) | catalogued as rs797045095, COSV100056263; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MPZ | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 172/419 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913589, CD103362, CM165580, CM960978, CM960979, COSV100337829; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 207/561 reads (37%) | catalogued as rs587779212, CM105419, COSV52273723; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTHFR | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 273/600 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121434296, CM960996; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NEB | c.1569+1G>A p.X523_splice | Splice Site (SNP) | VAF 197/428 reads (46%) | catalogued as rs1553605553, CS1413956, COSV51447294, COSV99423800; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NR5A1 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 265/564 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs375469069, CM080459; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- OCRL | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 155/343 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853263, CM050304, COSV63980555; ClinVar: not provided / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3073A>G p.T1025A | Missense Mutation (SNP) | VAF 279/615 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs397517202, CM126696, COSV55873252, COSV55911053, COSV55955422; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PLA2G6 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 254/554 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs370691849, CM063042; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RTTN | c.4295G>A p.R1432H | Missense Mutation (SNP) | VAF 179/408 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1465962355; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RXYLT1 | c.743+1G>A p.X248_splice | Splice Site (SNP) | VAF 98/253 reads (39%) | catalogued as rs778174763, COSV54170124, COSV54170575; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.1837C>T p.R613* | Nonsense Mutation (SNP) | VAF 331/776 reads (43%) | catalogued as rs398123585, CM065453, COSV57667669; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.5318C>T p.A1773V | Missense Mutation (SNP) | VAF 292/793 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1553463602, COSV51833269; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN8A | c.5614C>T p.R1872W | Missense Mutation (SNP) | VAF 235/475 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs796053228, CM147204, COSV61987040, COSV99050261; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SDHA | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 212/481 reads (44%) | catalogued as rs771328239, COSV53769941; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SEC23B | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 168/417 reads (40%) | catalogued as rs121918224, CM094613; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 305/647 reads (47%) | hotspot (GDC flag); catalogued as CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; called by muse, mutect2, varscan2
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 184/500 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- VEGFC | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 176/433 reads (41%) | catalogued as rs587777567, CM146336; ClinVar: pathogenic; called by muse, varscan2
- WDR72 | c.2686C>T p.R896* | Nonsense Mutation (SNP) | VAF 204/468 reads (44%) | catalogued as rs557128345, CM109077, COSV64751129; ClinVar: pathogenic; called by muse, mutect2, varscan2
- XDH | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 68/633 reads (11%) | catalogued as rs119460972, CM971597, COSV101052504, COSV65151007; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZEB2 | c.1027C>T p.R343* | Nonsense Mutation (SNP) | VAF 120/522 reads (23%) | catalogued as rs786204815, CM031406, COSV100356564; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZMYND11 | c.22C>T p.R8* | Nonsense Mutation (SNP) | VAF 203/476 reads (43%) | catalogued as rs1060499626; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AATK | c.2851C>T p.L951F (on ENST00000326724 / NM_001080395.3; = p.L848F on NM_004920.2) | Missense Mutation (SNP) | VAF 186/386 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs781241006; called by muse, mutect2, varscan2
- AATK | c.1934C>T p.T645M (on ENST00000326724 / NM_001080395.3; = p.T542M on NM_004920.2) | Missense Mutation (SNP) | VAF 148/358 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.288); catalogued as rs1342690620, COSV58368198; called by muse, mutect2, varscan2
- ABCA10 | c.4475C>T p.A1492V | Missense Mutation (SNP) | VAF 108/250 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as rs765919520, COSV52217900; called by muse, mutect2, varscan2
- ABCA12 | c.6004G>A p.A2002T (on ENST00000272895 / NM_173076.3; = p.A1684T on NM_015657.3) | Missense Mutation (SNP) | VAF 210/470 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767873608; called by muse, mutect2, varscan2
- ABCA12 | c.1211G>A p.R404Q (on ENST00000272895 / NM_173076.3; = p.R86Q on NM_015657.3) | Missense Mutation (SNP) | VAF 196/434 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs752328328, COSV55961290, COSV99789386; called by muse, mutect2, varscan2
- ABCA13 | c.5636G>A p.R1879Q | Missense Mutation (SNP) | VAF 263/545 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs763421969, COSV70026133, COSV70042106; called by muse, mutect2, varscan2
- ABCA13 | c.10294G>A p.A3432T | Missense Mutation (SNP) | VAF 68/740 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as rs1190105986, COSV71290199; called by muse, mutect2
- ABCA13 | c.11742A>C p.R3914S | Missense Mutation (SNP) | VAF 212/474 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71282995; called by muse, varscan2
- ABCA13 | c.13361G>A p.R4454H | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1280212847, COSV68946313; called by muse, mutect2, varscan2
- ABCA6 | c.4550C>T p.T1517M | Missense Mutation (SNP) | VAF 289/610 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.097); catalogued as rs377673526, COSV99445662; called by muse, mutect2, varscan2
- ABCB10 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 219/433 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs200713703; called by muse, mutect2, varscan2
- ABCB4 | c.2905C>T p.R969C | Missense Mutation (SNP) | VAF 114/262 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.892); catalogued as rs748571017; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.2683G>A p.A895T (on ENST00000404938 / NM_001163941.2; = p.A450T on NM_178559.6) | Missense Mutation (SNP) | VAF 152/398 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs755407075; called by muse, mutect2, varscan2
- ABCB5 | c.3080G>A p.R1027H (on ENST00000404938 / NM_001163941.2; = p.R582H on NM_178559.6) | Missense Mutation (SNP) | VAF 232/572 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs745749100, COSV51703658, COSV51718688; called by muse, mutect2, varscan2
- ABCB8 | c.665G>A p.R222H (on ENST00000297504 / NM_001282291.2; = p.R205H on NM_007188.5) | Missense Mutation (SNP) | VAF 250/550 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as rs765590229, COSV52502112; called by muse, mutect2, varscan2
- ABCC12 | c.3785G>A p.R1262H | Missense Mutation (SNP) | VAF 199/439 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760618518, COSV60913121; called by muse, mutect2, varscan2
- ABCC4 | c.3608C>T p.A1203V | Missense Mutation (SNP) | VAF 103/456 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373949612; called by muse, mutect2, varscan2
- ABCC4 | c.2671C>T p.R891C | Missense Mutation (SNP) | VAF 202/497 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs925622427; called by muse, mutect2, varscan2
- ABCC5 | c.739G>A p.G247S | Missense Mutation (SNP) | VAF 208/422 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as rs369624798; called by muse, mutect2, varscan2
- ABCC6 | c.2921A>G p.D974G | Missense Mutation (SNP) | VAF 144/453 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs147391297; called by muse, mutect2, varscan2
- ABCC8 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 261/616 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); catalogued as rs1048094; called by muse, mutect2, varscan2
- ABCC8 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 51/460 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs938611347; called by muse, mutect2, varscan2
- ABCC9 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 203/499 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.635); catalogued as rs781206225, COSV53987558; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC9 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 273/621 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770829231, COSV53969917; called by muse, mutect2, varscan2
- ABCF1 | c.1258C>T p.R420W (on ENST00000326195 / NM_001025091.2; = p.R382W on NM_001090.3) | Missense Mutation (SNP) | VAF 214/503 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs868768673; called by muse, mutect2, varscan2
- ABCF2 | c.1273C>T p.R425* | Nonsense Mutation (SNP) | VAF 56/896 reads (6%) | catalogued as rs773313474; called by muse, mutect2
- ABCF3 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 381/829 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs370468144; called by muse, mutect2, varscan2
- ABCG5 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 238/505 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs771475759; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCG8 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 275/585 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757824090, COSV99699915; called by muse, mutect2, varscan2
- ABCG8 | c.866G>A p.G289D | Missense Mutation (SNP) | VAF 95/217 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769842021; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCG8 | c.1269G>T p.E423D | Missense Mutation (SNP) | VAF 86/452 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs762861929, CM064944; called by muse, mutect2, varscan2
- ABHD12 | c.750C>T p.G250= | Splice Region (SNP) | VAF 186/337 reads (55%) | catalogued as rs541095122; called by muse, mutect2, varscan2
- ABHD17C | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 155/383 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.187); catalogued as rs753545613; called by muse, mutect2, varscan2
- ABHD5 | c.230C>A p.P77Q | Missense Mutation (SNP) | VAF 124/584 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1176576364; called by muse, mutect2, varscan2
- ABLIM1 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 198/461 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.577); catalogued as rs764878710; called by muse, mutect2, varscan2
- ABRA | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 280/697 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs543076495; called by muse, mutect2, varscan2
- ABT1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 36/665 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1336640036; called by muse, mutect2
- ABT1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 304/653 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs782364537, COSV51291580; called by muse, mutect2, varscan2
- ABTB2 | c.1471G>A p.G491S | Missense Mutation (SNP) | VAF 274/588 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1278994667; called by muse, mutect2, varscan2
- AC004997.1 | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 206/468 reads (44%) | SIFT deleterious, low confidence (0); catalogued as rs756306909, COSV57575126; called by muse, mutect2, varscan2
- AC011455.2 | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 154/348 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.325); catalogued as rs147888941; called by muse, mutect2, varscan2
- AC013477.1 | c.2485G>T p.D829Y | Missense Mutation (SNP) | VAF 241/528 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.903); catalogued as rs770583886; called by muse, mutect2, varscan2
- AC100868.1 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 108/1202 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.646); catalogued as COSV51849992; called by muse, mutect2
- AC127029.3 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 402/858 reads (47%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.965); catalogued as rs778008637; called by muse, varscan2
- AC144573.1 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 183/416 reads (44%) | SIFT deleterious, low confidence (0); catalogued as rs773676279; called by muse, mutect2, varscan2
- AC244197.3 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 228/573 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.052); catalogued as COSV61711372; called by muse, mutect2, varscan2
- ACACA | c.4087C>T p.R1363C | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs780539614; called by muse, mutect2, varscan2
- ACACA | c.2374C>T p.R792C | Missense Mutation (SNP) | VAF 260/607 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs765343770; called by muse, varscan2
- ACADM | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 107/284 reads (38%) | catalogued as rs1462279583; called by muse, mutect2, varscan2
- ACAN | c.5879G>A p.G1960D | Missense Mutation (SNP) | VAF 197/451 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as rs766231705; called by muse, mutect2, varscan2
- ACBD5 | c.1271G>A p.R424Q (on ENST00000375888 / NM_001352568.1; = p.R415Q on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 250/578 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.241); catalogued as rs543720340, COSV101022460; called by muse, mutect2, varscan2
- ACO2 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 236/530 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99347316; called by muse, varscan2
- ACOD1 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 67/308 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs767323284, COSV66291594; called by muse, mutect2, varscan2
- ACOT7 | c.791G>A p.R264H (on ENST00000377855 / NM_181864.3; = p.R254H on NM_007274.4) | Missense Mutation (SNP) | VAF 176/381 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201187410, COSV64114865; called by muse, mutect2, varscan2
- ACOT7 | c.253G>A p.A85T (on ENST00000377855 / NM_181864.3; = p.A75T on NM_007274.4) | Missense Mutation (SNP) | VAF 40/550 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.097); catalogued as rs1314714440, COSV64111832; called by muse, mutect2
- ACP2 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 171/412 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs776348174; called by muse, mutect2, varscan2
- ACSBG2 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 169/382 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777450290, COSV99397628; called by muse, mutect2, varscan2
- ACSF3 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 122/239 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as rs200536797, COSV58082413; called by muse, mutect2, varscan2
- ACSM4 | c.6G>T p.K2N | Missense Mutation (SNP) | VAF 77/218 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV68067432; called by muse, mutect2, varscan2
- ACSS1 | c.1429G>A p.V477I | Missense Mutation (SNP) | VAF 193/444 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs138608122; called by muse, mutect2, varscan2
- ACSS2 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 309/627 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs747577313; called by muse, mutect2, varscan2
- ACSS3 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 217/409 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs759930604, COSV54098822; called by muse, mutect2, varscan2
- ACTG2 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 212/473 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs753251409, COSV100608871, COSV61828300; called by muse, mutect2, varscan2
- ACTL6B | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 31/562 reads (6%) | catalogued as COSV50518157; called by muse, mutect2
- ACTN4 | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 106/267 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs200919223, COSV53143259; called by muse, varscan2
- ACTN4 | c.2437C>T p.R813C | Missense Mutation (SNP) | VAF 248/585 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs755524840, COSV99400031; called by muse, mutect2, varscan2
- ACTR5 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 52/550 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs768832312; called by muse, mutect2
- ACTR6 | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 216/489 reads (44%) | catalogued as rs1253396208, COSV51841209; called by muse, mutect2, varscan2
- ACVR1 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 249/573 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as rs765195676; called by muse, mutect2, varscan2
- ACVR2B | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 158/376 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.39); catalogued as rs1409388869; called by muse, mutect2, varscan2
- ADAM10 | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 83/318 reads (26%) | catalogued as COSV53050211, COSV53053502; called by muse, mutect2, varscan2
- ADAM12 | c.1136T>C p.I379T | Missense Mutation (SNP) | VAF 221/541 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1236616891; called by muse, mutect2, varscan2
- ADAM12 | c.943A>G p.T315A | Missense Mutation (SNP) | VAF 29/368 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1310105247; called by muse, mutect2
- ADAM17 | c.1819C>A p.L607I | Missense Mutation (SNP) | VAF 143/624 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs988994141; called by muse, mutect2, varscan2
- ADAM19 | c.2144C>T p.A715V | Missense Mutation (SNP) | VAF 112/450 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs375055045; called by muse, mutect2, varscan2
- ADAM28 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 211/519 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV99737808; called by muse, mutect2, varscan2
- ADAMDEC1 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 154/388 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as rs200386440; called by muse, mutect2, varscan2
- ADAMTS12 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 113/487 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61259417; called by muse, mutect2, varscan2
- ADAMTS13 | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 41/366 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as rs782223605, COSV100747160; called by muse, mutect2, varscan2
- ADAMTS14 | c.1927G>A p.A643T | Missense Mutation (SNP) | VAF 254/582 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs374298482, COSV64605114; called by muse, mutect2, varscan2
- ADAMTS15 | c.1916C>T p.T639M | Missense Mutation (SNP) | VAF 130/308 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs748324580; called by muse, mutect2, varscan2
- ADAMTS16 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 253/575 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs199521777; called by muse, mutect2, varscan2
- ADAMTS17 | c.3224G>A p.R1075H | Missense Mutation (SNP) | VAF 56/682 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs780853868, COSV51477135; called by muse, mutect2
- ADAMTS18 | c.877C>A p.L293I | Missense Mutation (SNP) | VAF 202/485 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.889); catalogued as COSV51420967; called by muse, mutect2, varscan2
- ADAMTS19 | c.1332A>C p.K444N | Missense Mutation (SNP) | VAF 92/229 reads (40%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.875); catalogued as COSV50735793, COSV50768551; called by muse, mutect2, varscan2
- ADAMTS19 | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 157/332 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs548757432, COSV50731429; called by muse, mutect2, varscan2
- ADAMTS19 | c.3106C>T p.R1036C | Missense Mutation (SNP) | VAF 198/485 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as rs749725000, COSV50744010; called by muse, mutect2, varscan2
- ADAMTS2 | c.3352G>A p.V1118M | Missense Mutation (SNP) | VAF 153/330 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.183); catalogued as rs148717330; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS2 | c.2229G>T p.E743D | Missense Mutation (SNP) | VAF 140/542 reads (26%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.984); catalogued as COSV52377868; called by muse, mutect2, varscan2
- ADAMTS20 | c.1703G>A p.C568Y | Missense Mutation (SNP) | VAF 178/433 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1407684080; called by muse, mutect2, varscan2
- ADAMTS3 | c.3587G>A p.R1196H | Missense Mutation (SNP) | VAF 156/377 reads (41%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs201592611; called by muse, mutect2, varscan2
- ADAMTS5 | c.1405+2T>C p.X469_splice | Splice Site (SNP) | VAF 20/464 reads (4%) | catalogued as COSV53177751; called by muse, mutect2
- ADAMTS6 | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 239/489 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.311); catalogued as rs746668287, COSV66858574, COSV66860426; called by muse, mutect2, varscan2
- ADAMTS8 | c.223C>A p.L75I | Missense Mutation (SNP) | VAF 103/464 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.233); catalogued as rs1168644927; called by muse, mutect2
- ADAMTS9 | c.5644G>A p.G1882S | Missense Mutation (SNP) | VAF 164/422 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs768864213; called by muse, mutect2, varscan2
- ADAMTSL5 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 163/353 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs774891231; called by muse, mutect2, varscan2
- ADCK5 | c.1666G>A p.A556T | Missense Mutation (SNP) | VAF 180/401 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0.019); catalogued as rs1042549844; called by muse, mutect2, varscan2
- ADCY1 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 227/530 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1178462101; called by muse, mutect2, varscan2
- ADCY6 | c.796G>T p.G266C | Missense Mutation (SNP) | VAF 254/580 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.593); catalogued as COSV100327070, COSV57169723; called by muse, varscan2
- ADCY6 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 130/266 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs760708097, COSV57166785; called by muse, varscan2
- ADCY9 | c.3641G>A p.R1214H | Missense Mutation (SNP) | VAF 208/479 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs200863972, COSV99569748; called by muse, mutect2, varscan2
- ADD1 | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 268/536 reads (50%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.011); catalogued as rs751882384; called by muse, mutect2, varscan2
- ADGRB1 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 203/427 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as COSV60100391; called by muse, varscan2
- ADGRB1 | c.4358C>T p.T1453M | Missense Mutation (SNP) | VAF 46/408 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs894061908; called by muse, mutect2, varscan2
- ADGRB2 | c.4052A>G p.Y1351C | Missense Mutation (SNP) | VAF 97/322 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770857327; called by muse, mutect2, varscan2
- ADGRB2 | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 230/518 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs768585899; called by muse, varscan2
- ADGRE2 | c.1636G>A p.V546I | Missense Mutation (SNP) | VAF 236/606 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs377330707; called by muse, mutect2, varscan2
- ADGRF1 | c.1523C>T p.T508M | Missense Mutation (SNP) | VAF 139/530 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs748429245, COSV51948635; called by muse, mutect2, varscan2
- ADGRG4 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 216/526 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs754146292; called by muse, mutect2, varscan2
- ADGRG4 | c.3029C>A p.P1010H | Missense Mutation (SNP) | VAF 111/470 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); catalogued as COSV54956566; called by muse, mutect2, varscan2
- ADGRL3 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 257/568 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV101547380; called by muse, mutect2, varscan2
- ADGRL3 | c.875G>A p.R292H (on ENST00000506720 / NM_001322402.2; = p.R224H on NM_015236.6) | Missense Mutation (SNP) | VAF 308/766 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747554116, COSV72269499; called by muse, mutect2, varscan2
- ADGRL3 | c.3800C>T p.A1267V (on ENST00000506720 / NM_001322402.2; = p.A1199V on NM_015236.6) | Missense Mutation (SNP) | VAF 174/380 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.317); catalogued as rs766739953, COSV101547009; called by muse, mutect2, varscan2
- ADGRV1 | c.3785A>G p.D1262G | Missense Mutation (SNP) | VAF 146/338 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs766493253; called by muse, mutect2, varscan2
- ADGRV1 | c.11806G>A p.V3936I | Missense Mutation (SNP) | VAF 199/470 reads (42%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs759082660, COSV67982214; called by muse, mutect2, varscan2
- ADGRV1 | c.15335G>A p.R5112H | Missense Mutation (SNP) | VAF 73/350 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs142891862; called by muse, mutect2, varscan2
- ADI1 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 34/435 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as rs764517683, COSV59376670; called by muse, mutect2
- ADPRH | c.929C>A p.A310D | Missense Mutation (SNP) | VAF 107/477 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63695388; called by muse, mutect2, varscan2
- ADPRHL1 | c.4313G>A p.R1438H | Missense Mutation (SNP) | VAF 131/269 reads (49%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs534218590; called by muse, mutect2, varscan2
- ADRA1B | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 134/294 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs983541290; called by muse, mutect2, varscan2
- ADRA2B | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 256/573 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1264061104; called by muse, mutect2, varscan2
- ADRB2 | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 137/303 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV60005852; called by muse, mutect2, varscan2
- AFAP1 | c.1937C>T p.A646V | Missense Mutation (SNP) | VAF 273/657 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs1365370863; called by muse, mutect2, varscan2
- AFF1 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 191/420 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.105); catalogued as rs368134000; called by muse, mutect2, varscan2
- AFF1 | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 230/576 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146841231; called by muse, mutect2, varscan2
- AFM | c.1403T>G p.F468C | Missense Mutation (SNP) | VAF 32/608 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56919493; called by muse, mutect2
- AGAP2 | c.1592G>A p.R531H (on ENST00000547588 / NM_001122772.2; = p.R195H on NM_014770.4) | Missense Mutation (SNP) | VAF 18/430 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1246757284, COSV99224706; called by muse, mutect2
- AGBL1 | c.1915G>A p.G639S | Missense Mutation (SNP) | VAF 251/545 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as rs180793760, COSV66863776; called by muse, mutect2, varscan2
- AGBL3 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 144/534 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.674); catalogued as rs901299301; called by muse, mutect2, varscan2
- AGER | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 121/313 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV61248874; called by muse, mutect2, varscan2
- AGFG1 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 52/572 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59511216; called by muse, mutect2
- AGO1 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 214/520 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as rs745615692, COSV64595185; called by muse, mutect2, varscan2
- AGO2 | c.2561G>A p.R854H | Missense Mutation (SNP) | VAF 180/486 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs756991172, COSV55053634; called by muse, varscan2
- AGO4 | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 146/402 reads (36%) | catalogued as COSV64617889; called by muse, mutect2, varscan2
- AGPAT1 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 57/712 reads (8%) | catalogued as COSV61246915, COSV61248990; called by muse, mutect2
- AGPAT5 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 201/464 reads (43%) | catalogued as rs752941173, COSV53446129; called by muse, mutect2, varscan2
- AGPS | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 32/419 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV51566645; called by muse, mutect2
- AGRN | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 42/548 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.031); catalogued as rs758854920, COSV65069738; called by muse, mutect2
- AGRN | c.3694C>T p.R1232C | Missense Mutation (SNP) | VAF 250/524 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs777331097, COSV101038791; called by muse, mutect2, varscan2
- AHCTF1 | c.6453G>T p.E2151D (on ENST00000366508; = p.E2125D on NM_015446.5) | Missense Mutation (SNP) | VAF 270/608 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs375402511; called by muse, mutect2, varscan2
- AHCTF1 | c.5896C>T p.R1966C (on ENST00000366508; = p.R1940C on NM_015446.5) | Missense Mutation (SNP) | VAF 204/434 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs1226434538, COSV58251075; called by muse, mutect2, varscan2
- AHCTF1 | c.1349C>T p.S450L (on ENST00000366508; = p.S424L on NM_015446.5) | Missense Mutation (SNP) | VAF 78/346 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs528013816, COSV58246078; called by muse, mutect2, varscan2
- AHCY | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 295/635 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as rs1276848587; called by muse, mutect2, varscan2
- AHDC1 | c.4532C>T p.T1511M | Missense Mutation (SNP) | VAF 183/422 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs746077736; called by muse, mutect2, varscan2
- AHNAK | c.11318A>G p.D3773G | Missense Mutation (SNP) | VAF 251/606 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.942); catalogued as COSV57210935; called by muse, mutect2, varscan2
- AHNAK | c.11080C>T p.P3694S | Missense Mutation (SNP) | VAF 196/424 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs767396408; called by muse, varscan2
- AHNAK | c.5438C>T p.P1813L | Missense Mutation (SNP) | VAF 326/708 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756084082, COSV57210444; called by muse, mutect2, varscan2
- AHNAK2 | c.11446T>G p.S3816A | Missense Mutation (SNP) | VAF 128/316 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.475); catalogued as COSV60914667; called by muse, mutect2
- AHNAK2 | c.7741C>A p.L2581I | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT tolerated (0.76); PolyPhen benign (0.042); catalogued as rs868775761; called by muse, mutect2, varscan2
- AHNAK2 | c.1636C>T p.H546Y | Missense Mutation (SNP) | VAF 144/302 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs776852227; called by muse, mutect2, varscan2
- AHR | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 194/489 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as rs545782208, COSV54123074; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AIRE | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 132/313 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs561652010; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AJM1 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 48/438 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs764134799; called by muse, varscan2
- AK8 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 135/365 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100049687; called by muse, mutect2, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 73/230 reads (32%) | catalogued as rs778351035; called by mutect2, pindel, varscan2
- AKAP10 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 284/648 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs767264107, COSV56732331; called by muse, varscan2
- AKAP11 | c.3886G>A p.E1296K | Missense Mutation (SNP) | VAF 241/522 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs576236263, COSV99213747; called by muse, mutect2, varscan2
- AKAP11 | c.4942G>A p.A1648T | Missense Mutation (SNP) | VAF 333/661 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50292502; called by muse, mutect2, varscan2
- AKAP13 | c.3586C>T p.P1196S | Missense Mutation (SNP) | VAF 81/171 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.388); catalogued as rs777066587; called by muse, mutect2, varscan2
- AKAP13 | c.8020C>T p.R2674W (on ENST00000394518 / NM_007200.5; = p.R2678W on NM_006738.6) | Missense Mutation (SNP) | VAF 156/374 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs773151980, COSV100773154; called by muse, varscan2
- AKAP8L | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 221/474 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs576284598; called by muse, mutect2, varscan2
- AKR1B1 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 174/408 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs1380748552, COSV53646649; called by muse, mutect2, varscan2
- AKR1B1 | c.234+6G>A | Splice Region (SNP) | VAF 235/543 reads (43%) | catalogued as rs757943324; called by muse, mutect2, varscan2
- AKR1D1 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 162/416 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs368152787, COSV54338420; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKT1 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 296/650 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as rs1219649544, COSV100837901; called by muse, mutect2, varscan2
- AKT3 | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 102/254 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV55629231; called by muse, mutect2, varscan2
- AL133500.1 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 218/432 reads (50%) | SIFT tolerated, low confidence (0.16); catalogued as rs751916691, COSV99860492; called by muse, mutect2, varscan2
- AL358113.1 | c.3887G>A p.R1296H | Missense Mutation (SNP) | VAF 274/592 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs370985421, COSV61957484; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH16A1 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 241/490 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs372942000, COSV53196726; called by muse, mutect2, varscan2
- ALDH1A2 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 173/418 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV104375433; called by muse, mutect2, varscan2
- ALDH1A3 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 129/285 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs150542846; called by muse, mutect2, varscan2
- ALDH3B1 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 354/722 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs924552858; called by muse, mutect2, varscan2
- ALDH5A1 | c.1474G>A p.V492I | Missense Mutation (SNP) | VAF 263/617 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs151294087; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH6A1 | c.1250A>G p.E417G | Missense Mutation (SNP) | VAF 133/343 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100620828; called by muse, mutect2, varscan2
- ALDH7A1 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 93/357 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as rs771975420, COSV63160888; called by muse, mutect2, varscan2
- ALG9 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 246/559 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782123768, COSV67644339; called by muse, mutect2, varscan2
- ALKBH8 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1030810061; called by muse, mutect2, varscan2
- ALMS1 | c.2296C>T p.Q766* | Nonsense Mutation (SNP) | VAF 136/316 reads (43%) | catalogued as CM121101; called by muse, mutect2, varscan2
- ALMS1 | c.3278C>T p.P1093L | Missense Mutation (SNP) | VAF 170/395 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs766187468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX5 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 53/1058 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as rs1441615039; called by muse, mutect2
- ALOXE3 | c.483C>A p.S161R | Missense Mutation (SNP) | VAF 51/1064 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as COSV59075303; called by muse, mutect2
- ALPI | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 66/780 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1445528675, COSV55013473; called by muse, mutect2
- ALPK1 | c.3028G>T p.A1010S | Missense Mutation (SNP) | VAF 98/535 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1255438832, COSV51592698; called by mutect2, varscan2
- ALPK2 | c.5747G>A p.G1916D | Missense Mutation (SNP) | VAF 185/402 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64494612; called by muse, mutect2, varscan2
- ALPK3 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 254/576 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs116593882; called by muse, mutect2, varscan2
- ALPK3 | c.4000G>A p.V1334M | Missense Mutation (SNP) | VAF 238/496 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs377209768; called by muse, varscan2
- ALS2 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 193/447 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1380105818; called by muse, mutect2, varscan2
- AMBRA1 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 20/602 reads (3%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.028); catalogued as rs1485307299; called by muse, mutect2
- AMER1 | c.1645C>T p.R549W | Missense Mutation (SNP) | VAF 199/438 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs746279756; called by muse, mutect2, varscan2
- AMHR2 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 122/316 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs767904039, COSV57684903; called by muse, mutect2, varscan2
- AMOT | c.1232C>T p.P411L (on ENST00000371959 / NM_001113490.1; = p.P2L on NM_133265.3) | Missense Mutation (SNP) | VAF 367/696 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs751275612; called by muse, mutect2, varscan2
- AMOTL1 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 35/420 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.098); catalogued as rs371806495, COSV54414848; called by muse, mutect2
- AMPH | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 134/516 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs776397586, COSV100344102; called by muse, mutect2, varscan2
- AMY2A | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 215/632 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758134251, COSV101340634, COSV101340678; called by muse, mutect2, varscan2
- AMZ1 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 252/541 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs375171083; called by muse, mutect2, varscan2
- ANGEL2 | c.642C>T p.D214= | Splice Region (SNP) | VAF 109/216 reads (50%) | catalogued as rs1318215998, COSV64738414; called by muse, mutect2, varscan2
- ANHX | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 137/378 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as rs1415552396; called by muse, mutect2, varscan2
- ANK1 | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 198/481 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs772536407, COSV55884253; called by muse, varscan2
- ANK2 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 139/317 reads (44%) | catalogued as rs146907003, COSV52159416; called by muse, mutect2, varscan2
- ANK3 | c.12152C>T p.T4051M | Missense Mutation (SNP) | VAF 56/716 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.23); catalogued as rs531332857, COSV55043015; called by muse, mutect2
- ANK3 | c.7448C>T p.S2483L | Missense Mutation (SNP) | VAF 72/319 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs147863456; called by muse, mutect2, varscan2
- ANKDD1B | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 238/532 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.662); catalogued as rs773851670; called by muse, mutect2, varscan2
- ANKFN1 | c.572G>T p.R191M | Missense Mutation (SNP) | VAF 56/635 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100593219, COSV59441784; called by muse, mutect2
- ANKFY1 | c.3319G>A p.G1107S (on ENST00000341657 / NM_001330063.2; = p.G1108S on NM_016376.5) | Missense Mutation (SNP) | VAF 130/273 reads (48%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.634); catalogued as COSV58919874; called by muse, varscan2
- ANKFY1 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 174/394 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.495); catalogued as rs147745463, COSV100492449; called by muse, varscan2
- ANKRD12 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 163/358 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50819927; called by muse, mutect2, varscan2
- ANKRD13B | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 307/765 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1319329190; called by muse, mutect2, varscan2
- ANKRD13D | c.*382C>T | Splice Region (SNP) | VAF 168/401 reads (42%) | catalogued as rs780542122; called by muse, mutect2, varscan2
- ANKRD17 | c.1184C>T p.T395M | Missense Mutation (SNP) | VAF 180/418 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs770504687, COSV58216064; called by muse, mutect2, varscan2
- ANKRD2 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 211/453 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.1); catalogued as rs770433937, COSV100080816; called by muse, mutect2, varscan2
- ANKRD2 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 291/640 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.469); catalogued as rs368630525; called by muse, mutect2, varscan2
- ANKRD30A | c.584del p.N195Mfs*26 (on ENST00000611781; = p.N139Mfs*26 on NM_052997.2) | Frame Shift Del (DEL) | VAF 159/463 reads (34%) | catalogued as COSV64613285; called by mutect2, pindel, varscan2
- ANKRD36C | c.4124G>A p.R1375H | Missense Mutation (SNP) | VAF 85/645 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201616266, COSV69431241; called by muse, mutect2, varscan2
- ANKRD44 | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 239/566 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774090343, COSV56550946; called by muse, mutect2, varscan2
- ANKRD44 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 36/524 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99985541; called by muse, mutect2
- ANKRD52 | c.2713G>A p.A905T | Missense Mutation (SNP) | VAF 44/670 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.227); catalogued as rs969711869; called by muse, mutect2
- ANKRD52 | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 175/767 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.545); catalogued as rs1244186415; called by muse, varscan2
- ANKS3 | c.973C>T p.R325W | Missense Mutation (SNP) | VAF 141/330 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs200655172, COSV58508242; called by muse, mutect2, varscan2
- ANLN | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 190/447 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs774583975; called by muse, mutect2, varscan2
- ANLN | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 53/472 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs775815569; called by muse, mutect2, varscan2
- ANO3 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 178/402 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs376935363; called by muse, varscan2
- ANO6 | c.2255G>A p.R752H | Missense Mutation (SNP) | VAF 117/550 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs375384540; called by muse, mutect2, varscan2
- ANO8 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 147/374 reads (39%) | catalogued as rs775954499, COSV50173959; called by muse, mutect2, varscan2
- ANPEP | c.940G>A p.G314S | Missense Mutation (SNP) | VAF 53/335 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.577); catalogued as rs148047449; called by muse, mutect2, varscan2
- ANXA4 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 300/710 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1330993366; called by muse, mutect2, varscan2
- AOC1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 378/856 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs367665701; called by muse, mutect2
- AOC2 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 203/516 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs1555552227, COSV53199505; called by muse, mutect2, varscan2
- AOPEP | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 186/392 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs375204570; called by muse, mutect2, varscan2
- AOX1 | c.1875G>A p.V625= | Splice Region (SNP) | VAF 23/369 reads (6%) | catalogued as COSV65983275; called by muse, mutect2
- AP1M1 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 141/330 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as rs745679023; called by muse, mutect2, varscan2
- AP2A1 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 196/425 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1188956541, COSV100756566; called by muse, varscan2
- AP2A1 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 149/364 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs371530889; called by muse, mutect2, varscan2
- AP2A2 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 252/568 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs542944302; called by muse, varscan2
- AP2M1 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 44/848 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as rs1431035134, COSV53047259; called by muse, mutect2
- AP2M1 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 49/461 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as rs1313715106; called by muse, mutect2, varscan2
- AP3B1 | c.827C>A p.S276Y | Missense Mutation (SNP) | VAF 137/371 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54888175, COSV99670591; called by muse, mutect2, varscan2
- AP3B2 | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 286/610 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs375481337; called by muse, mutect2, varscan2
- AP3D1 | c.1951C>T p.R651W | Missense Mutation (SNP) | VAF 224/530 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs765841034; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP3M2 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 94/392 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1326404336, COSV51529531; called by muse, mutect2, varscan2
- AP4M1 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 133/318 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs575096086; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APBA3 | c.1201C>T p.R401* | Nonsense Mutation (SNP) | VAF 99/231 reads (43%) | catalogued as rs201602109; called by muse, mutect2, varscan2
- APBB1 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 280/659 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs758804617, COSV54980743, COSV54981129; called by muse, mutect2, varscan2
- APC | c.8162G>A p.R2721H | Missense Mutation (SNP) | VAF 198/427 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs587780606, COSV57383058; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APLF | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 150/322 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as COSV58147760; called by muse, mutect2, varscan2
- APLF | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 34/424 reads (8%) | catalogued as rs773250190, COSV58148815; called by muse, mutect2
- APLP1 | c.1658C>T p.A553V (on ENST00000221891 / NM_001024807.3; = p.A552V on NM_005166.4) | Missense Mutation (SNP) | VAF 140/324 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1156249745, COSV55705407; called by muse, mutect2, varscan2
- APLP2 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 38/530 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs1045686751; called by muse, mutect2
- APOB | c.4862C>A p.S1621Y | Missense Mutation (SNP) | VAF 22/562 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51940164, COSV99267469; called by muse, mutect2
- APOB | c.1679C>A p.A560D | Missense Mutation (SNP) | VAF 248/600 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749886609; called by muse, mutect2, varscan2
- APOBEC3B | c.897G>T p.E299D | Missense Mutation (SNP) | VAF 141/161 reads (88%) | SIFT tolerated (0.22); PolyPhen benign (0.097); catalogued as COSV100213769; called by muse, mutect2, varscan2
- APOBEC3G | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 389/805 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1169111749; called by muse, mutect2, varscan2
- ARAF | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 186/732 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV51695297; called by muse, mutect2, varscan2
- ARAP1 | c.1952G>A p.R651H (on ENST00000393609 / NM_001040118.2; = p.R406H on NM_015242.4) | Missense Mutation (SNP) | VAF 184/620 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs201068078; called by muse, mutect2, varscan2
- ARAP2 | c.4057G>T p.A1353S | Missense Mutation (SNP) | VAF 154/346 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.557); catalogued as COSV100394155; called by muse, varscan2
- ARAP2 | c.2981G>A p.W994* | Nonsense Mutation (SNP) | VAF 202/468 reads (43%) | catalogued as COSV58293566; called by muse, varscan2
- ARAP3 | c.3509G>A p.R1170H | Missense Mutation (SNP) | VAF 194/416 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs116485474, COSV53351236; called by muse, mutect2, varscan2
- ARF3 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 30/638 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV56741604; called by muse, mutect2
- ARF5 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 309/681 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.944); catalogued as rs1286936912, COSV50001634; called by muse, mutect2, varscan2
- ARFGAP1 | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 241/520 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.067); catalogued as rs765995185; called by muse, mutect2, varscan2
- ARFGAP1 | c.899G>A p.G300D | Missense Mutation (SNP) | VAF 141/321 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1020826582; called by muse, mutect2, varscan2
- ARFGAP3 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 118/301 reads (39%) | catalogued as rs749122444; called by muse, mutect2, varscan2
- ARFGEF1 | c.3992C>T p.A1331V | Missense Mutation (SNP) | VAF 227/533 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs767341513, COSV51617000; called by muse, mutect2, varscan2
- ARFGEF2 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 221/497 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as rs762961927; called by muse, mutect2, varscan2
- ARFGEF2 | c.2557C>T p.R853W | Missense Mutation (SNP) | VAF 149/354 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64214823; called by muse, mutect2, varscan2
- ARFGEF3 | c.5611C>T p.P1871S | Missense Mutation (SNP) | VAF 142/303 reads (47%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.824); catalogued as rs1310538751; called by muse, mutect2, varscan2
- ARHGAP10 | c.2186G>A p.R729H | Missense Mutation (SNP) | VAF 143/350 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as rs368070329, COSV60597906; called by muse, mutect2, varscan2
- ARHGAP11A | c.1387C>T p.R463* | Nonsense Mutation (SNP) | VAF 25/223 reads (11%) | catalogued as rs749476119; called by muse, mutect2, varscan2
- ARHGAP17 | c.2071G>A p.A691T (on ENST00000289968 / NM_001006634.3; = p.A613T on NM_018054.6) | Missense Mutation (SNP) | VAF 87/408 reads (21%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs770746078, COSV51506948; called by muse, mutect2, varscan2
- ARHGAP21 | c.2247G>T p.Q749H | Missense Mutation (SNP) | VAF 294/722 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV57602477; called by muse, mutect2, varscan2
- ARHGAP27 | c.1602C>A p.F534L (on ENST00000428638 / NM_001282290.1; = p.F193L on NM_199282.3) | Missense Mutation (SNP) | VAF 154/332 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65358940; called by mutect2, varscan2
- ARHGAP28 | c.1778C>T p.A593V (on ENST00000383472 / NM_001366230.1; = p.A434V on NM_001010000.3) | Missense Mutation (SNP) | VAF 161/183 reads (88%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as rs761706342; called by muse, mutect2, varscan2
- ARHGAP30 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 168/324 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765956977; called by muse, mutect2, varscan2
- ARHGAP31 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 279/604 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs368670775; called by muse, mutect2, varscan2
- ARHGAP31 | c.3596C>T p.A1199V | Missense Mutation (SNP) | VAF 141/344 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs534166705, COSV51792586; called by muse, varscan2
- ARHGAP32 | c.5543C>T p.T1848M (on ENST00000310343 / NM_001378025.1; = p.T1499M on NM_014715.4) | Missense Mutation (SNP) | VAF 194/449 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs577826686; called by muse, mutect2, varscan2
- ARHGAP32 | c.4073C>T p.A1358V (on ENST00000310343 / NM_001378025.1; = p.A1009V on NM_014715.4) | Missense Mutation (SNP) | VAF 346/384 reads (90%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs763252101, COSV59852325; called by muse, mutect2, varscan2
- ARHGAP32 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 180/395 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs369224664; called by muse, mutect2, varscan2
- ARHGAP33 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 273/565 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs757101169; called by muse, varscan2
- ARHGAP35 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 29/298 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as rs781567899, COSV68331707; called by muse, mutect2
- ARHGAP35 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 25/462 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.635); catalogued as rs1055753203, COSV68330084; called by muse, mutect2
- ARHGAP39 | c.2762C>T p.A921V (on ENST00000276826 / NM_001308208.2; = p.A952V on NM_025251.2) | Missense Mutation (SNP) | VAF 75/175 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV52772332; called by muse, varscan2
- ARHGAP39 | c.2704C>T p.R902C (on ENST00000276826 / NM_001308208.2; = p.R933C on NM_025251.2) | Missense Mutation (SNP) | VAF 74/158 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as rs1378531747, COSV52766881; called by muse, varscan2
- ARHGAP39 | c.2671G>A p.A891T (on ENST00000276826 / NM_001308208.2; = p.A922T on NM_025251.2) | Missense Mutation (SNP) | VAF 102/216 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs371456040; called by muse, varscan2
- ARHGAP39 | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 274/670 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs755955179, COSV52776232; called by muse, varscan2
- ARHGAP5 | c.1765G>A p.D589N | Missense Mutation (SNP) | VAF 176/392 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs771017864; called by muse, mutect2, varscan2
- ARHGEF10L | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 107/394 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs1363268095; called by muse, mutect2, varscan2
- ARHGEF10L | c.2663C>T p.A888V | Missense Mutation (SNP) | VAF 283/572 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1326511003; called by muse, mutect2, varscan2
- ARHGEF10L | c.3757G>A p.A1253T | Missense Mutation (SNP) | VAF 180/568 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs750512347; called by muse, mutect2, varscan2
- ARHGEF17 | c.3856C>T p.R1286W | Missense Mutation (SNP) | VAF 36/587 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55231327; called by muse, mutect2
- ARHGEF18 | c.1321C>T p.R441W (on ENST00000359920 / NM_001130955.2; = p.R337W on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 168/344 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367800762; called by muse, varscan2
- ARHGEF18 | c.2521C>T p.R841C (on ENST00000359920 / NM_001130955.2; = p.R737C on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/369 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as rs1212623135; called by muse, mutect2, varscan2
- ARHGEF2 | c.422G>A p.R141H (on ENST00000361247 / NM_001162383.2; = p.R114H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 328/755 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as rs1266667140; called by muse, mutect2, varscan2
- ARHGEF26 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 234/557 reads (42%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs754939922, COSV62844469; called by muse, mutect2, varscan2
- ARHGEF28 | c.36G>A p.G12= | Splice Region (SNP) | VAF 84/245 reads (34%) | catalogued as rs757452890; called by muse, mutect2, varscan2
- ARHGEF37 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 309/779 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs567909765, COSV61367758; called by muse, mutect2, varscan2
- ARHGEF40 | c.2467C>T p.R823* | Nonsense Mutation (SNP) | VAF 29/490 reads (6%) | catalogued as rs1173848876; called by muse, mutect2
- ARID1A | c.2974G>T p.E992* | Nonsense Mutation (SNP) | VAF 163/378 reads (43%) | catalogued as COSV61372304; called by muse, mutect2, varscan2
- ARID1A | c.4987G>T p.D1663Y | Missense Mutation (SNP) | VAF 63/346 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61375057; called by muse, mutect2, varscan2
- ARID4A | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 196/518 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs770373766, COSV62162543; called by muse, mutect2, varscan2
- ARID4A | c.2002C>T p.R668* | Nonsense Mutation (SNP) | VAF 261/561 reads (47%) | catalogued as rs1335885003; called by muse, mutect2, varscan2
- ARID5A | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 159/357 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs139848963, COSV62591023; called by muse, mutect2, varscan2
- ARID5A | c.1699C>A p.L567I | Missense Mutation (SNP) | VAF 24/561 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as COSV62591104; called by muse, mutect2
- ARL2 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 38/373 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1336838890, COSV55861647; called by muse, mutect2, varscan2
- ARL4A | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 123/348 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs752253129; called by muse, mutect2, varscan2
- ARL4D | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 196/421 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60721351; called by muse, mutect2, varscan2
- ARL4D | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 225/398 reads (57%) | SIFT tolerated (0.57); PolyPhen benign (0.066); catalogued as rs866011666; called by muse, mutect2, varscan2
- ARL6IP1 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 295/679 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as rs546548310; called by muse, mutect2, varscan2
- ARL6IP6 | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 53/656 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs371666118; called by muse, mutect2
- ARMC12 | c.562C>T p.R188* (on ENST00000373866 / NM_001286574.2; = p.R215* on NM_145028.5) | Nonsense Mutation (SNP) | VAF 274/619 reads (44%) | catalogued as rs139872715; called by muse, mutect2, varscan2
- ARMC3 | c.841T>C p.S281P | Missense Mutation (SNP) | VAF 44/604 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV53058982; called by muse, mutect2
- ARMC4 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 179/433 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs200127444, COSV59459824; called by muse, mutect2, varscan2
- ARMC9 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 154/370 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs562097929, COSV63021989; called by muse, varscan2
- ARMH2 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 54/862 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs537677755; called by muse, mutect2
- ARMH4 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 43/496 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as rs767027409, COSV50762458; called by muse, mutect2
- ARNT | c.697A>G p.T233A | Missense Mutation (SNP) | VAF 23/445 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.869); catalogued as COSV62231209; called by muse, mutect2
- ARPC2 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 148/605 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as rs1257537129; called by muse, mutect2, varscan2
- ARPP21 | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 54/769 reads (7%) | catalogued as rs192238724, COSV51793695; called by muse, mutect2
- ARRB2 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 177/423 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as rs373325288; called by muse, mutect2, varscan2
- ARSI | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 120/230 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as rs750870834; called by muse, varscan2
- ARSK | c.968A>G p.Q323R | Missense Mutation (SNP) | VAF 39/683 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1335758499; called by muse, mutect2
- ARSL | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 160/400 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as COSV66964997; called by muse, varscan2
- ARVCF | c.2857G>A p.A953T | Missense Mutation (SNP) | VAF 24/522 reads (5%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs919196923; called by muse, mutect2
- ASAH1 | c.234G>A p.W78* | Nonsense Mutation (SNP) | VAF 221/487 reads (45%) | catalogued as rs769683272; called by muse, mutect2, varscan2
- ASAH2 | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 37/350 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272785683; called by muse, mutect2, varscan2
- ASAP3 | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 222/476 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.263); catalogued as rs774990747, COSV60873604; called by muse, varscan2
- ASB10 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 127/287 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as rs764682358; called by muse, mutect2, varscan2
- ASB2 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 172/370 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs200689971, COSV60112158, COSV60114316; called by muse, varscan2
- ASB7 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 204/433 reads (47%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.831); catalogued as rs755679645, COSV58403860; called by muse, mutect2, varscan2
- ASB8 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 72/337 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs754077245; called by muse, mutect2, varscan2
- ASCC3 | c.2432C>T p.T811M | Missense Mutation (SNP) | VAF 203/462 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111572743; called by muse, mutect2, varscan2
- ASGR2 | c.511G>A p.G171S | Missense Mutation (SNP) | VAF 273/570 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs147967898; called by muse, mutect2, varscan2
- ASH2L | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 126/277 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as rs1188787801; called by muse, mutect2, varscan2
- ASL | c.1127A>G p.Y376C | Missense Mutation (SNP) | VAF 171/348 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761034915; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASMTL | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 246/695 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs776878267, COSV67242719; called by muse, mutect2, varscan2
- ASNSD1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 253/502 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs1271827593; called by muse, mutect2, varscan2
- ASPG | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 214/444 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.061); catalogued as rs1323568640; called by muse, varscan2
- ASPG | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 44/478 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as rs748461343; called by muse, mutect2
- ASPM | c.10372G>T p.E3458* | Nonsense Mutation (SNP) | VAF 152/390 reads (39%) | catalogued as COSV99660313; called by mutect2, varscan2
- ASPM | c.2561G>A p.R854H | Missense Mutation (SNP) | VAF 62/579 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99660716; called by muse, mutect2, varscan2
- ASTN1 | c.3797C>T p.A1266V | Missense Mutation (SNP) | VAF 167/416 reads (40%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs934363990, COSV100706651, COSV62494925; called by muse, mutect2, varscan2
- ASTN2 | c.1268G>A p.R423H (on ENST00000313400 / NM_001365069.1; = p.R372H on NM_014010.5) | Missense Mutation (SNP) | VAF 165/390 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.964); catalogued as rs149596951; called by muse, mutect2, varscan2
- ASTN2 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 234/530 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1387133062, COSV57767504; called by muse, varscan2
- ASTN2 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 301/584 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs748550947, COSV100526472, COSV57751743; called by muse, varscan2
- ASXL1 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 290/637 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV60102799, COSV60105360; called by muse, mutect2, varscan2
- ASXL3 | c.4240G>A p.A1414T | Missense Mutation (SNP) | VAF 70/625 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as rs371206369, COSV52474612; called by muse, mutect2, varscan2
- ATAD2 | c.631A>G p.T211A | Missense Mutation (SNP) | VAF 83/342 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99785012; called by muse, mutect2, varscan2
- ATAD2B | c.3477del p.D1160Mfs*20 | Frame Shift Del (DEL) | VAF 220/454 reads (48%) | catalogued as rs1558490574; called by mutect2, varscan2
- ATF6 | c.1151T>C p.V384A | Missense Mutation (SNP) | VAF 66/288 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs1255258484; called by muse, mutect2, varscan2
- ATF7IP | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 36/522 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1315984500; called by muse, mutect2
- ATG16L2 | c.1245+7C>T | Splice Region (SNP) | VAF 163/398 reads (41%) | catalogued as rs371279032; called by muse, mutect2, varscan2
- ATG16L2 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 321/699 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as rs751853489, COSV58361496; called by muse, mutect2, varscan2
- ATG2A | c.954G>T p.K318N | Missense Mutation (SNP) | VAF 274/555 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV101034769; called by mutect2, varscan2
- ATG9A | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 327/763 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs752441032; called by muse, mutect2, varscan2
- ATIC | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 176/448 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs751418575, COSV52692736, COSV52695749; called by muse, mutect2, varscan2
- ATM | c.7043C>T p.T2348M | Missense Mutation (SNP) | VAF 111/542 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV99589678; called by muse, mutect2, varscan2
- ATN1 | c.1228C>T p.H410Y | Missense Mutation (SNP) | VAF 50/375 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); catalogued as rs782679725, COSV63111091; called by muse, mutect2
- ATP10A | c.3985C>T p.R1329C | Missense Mutation (SNP) | VAF 58/676 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs777738173, COSV63516773; called by muse, mutect2
- ATP10A | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 167/376 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as rs751938420, COSV63517024; called by muse, varscan2
- ATP10B | c.2000C>A p.S667Y | Missense Mutation (SNP) | VAF 178/406 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV59148108; called by muse, varscan2
- ATP10B | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 238/546 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs759177708; called by muse, mutect2, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 78/195 reads (40%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP13A2 | c.3112G>A p.A1038T | Missense Mutation (SNP) | VAF 150/410 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as rs757076945, COSV58704561; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP1A1 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 201/429 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.201); catalogued as rs141400264; called by muse, mutect2, varscan2
- ATP2A3 | c.2653G>A p.G885S | Missense Mutation (SNP) | VAF 422/877 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.331); catalogued as rs149912039; called by muse, mutect2, varscan2
- ATP2B1 | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 241/492 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs752025186; called by muse, mutect2, varscan2
- ATP2B2 | c.1828C>T p.R610C (on ENST00000352432; = p.R576C on NM_001683.5) | Missense Mutation (SNP) | VAF 175/423 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757018981, COSV100659980, COSV59498430; called by muse, mutect2, varscan2
- ATP2B2 | c.1490G>A p.R497H (on ENST00000352432; = p.R463H on NM_001683.5) | Missense Mutation (SNP) | VAF 229/499 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs758734872; called by muse, mutect2, varscan2
- ATP2B4 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 179/427 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs761844132; called by muse, mutect2, varscan2
- ATP2C1 | c.2291G>A p.R764H | Missense Mutation (SNP) | VAF 180/402 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358466833, COSV60756111; called by muse, mutect2, varscan2
- ATP2C2 | c.2008G>A p.A670T | Missense Mutation (SNP) | VAF 259/582 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV52296254; called by muse, varscan2
- ATP5MGL | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 120/297 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs774108301; called by muse, mutect2, varscan2
- ATP6AP2 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 152/370 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as rs761302416, COSV65797564; called by muse, varscan2
- ATP6V0A1 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 223/539 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs780783054; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1143G>T p.Q381H | Missense Mutation (SNP) | VAF 158/334 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as rs782326453; called by mutect2, varscan2
- ATP6V1G1 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 243/554 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs765667517; called by muse, mutect2, varscan2
- ATP7A | c.2242G>A p.V748I | Missense Mutation (SNP) | VAF 209/439 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782104015, COSV58452113; called by muse, mutect2, varscan2
- ATP8B4 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 131/307 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757819006; called by muse, mutect2, varscan2
- ATPAF2 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 165/388 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs755734025; called by muse, mutect2, varscan2
- ATR | c.7724C>T p.A2575V | Missense Mutation (SNP) | VAF 62/766 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.304); catalogued as rs762196224, COSV63387071; called by muse, mutect2
- ATR | c.984G>A p.M328I | Missense Mutation (SNP) | VAF 26/654 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs1426228305; called by muse, mutect2
- ATRIP | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 282/684 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as rs370096586; called by muse, mutect2, varscan2
- ATRX | c.4510C>T p.R1504* | Nonsense Mutation (SNP) | VAF 188/373 reads (50%) | catalogued as COSV64872902; called by muse, mutect2, varscan2
- ATXN2L | c.3098G>A p.G1033D | Missense Mutation (SNP) | VAF 169/893 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.177); catalogued as rs776492688; called by muse, mutect2, varscan2
- ATXN3L | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 257/636 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs1037712907, COSV66075382, COSV66076328; called by muse, mutect2, varscan2
- AURKA | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 88/463 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs749883403, COSV57167364; called by muse, mutect2, varscan2
- AURKB | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 38/640 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1322292985, COSV60243500; called by muse, mutect2
- AUTS2 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 128/312 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV61411806; called by muse, mutect2, varscan2
- AUTS2 | c.1484G>A p.R495Q | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61388180; called by muse, mutect2, varscan2
- AXIN2 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 606/665 reads (91%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as rs767445163, COSV61059799; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AXL | c.1501C>T p.R501C (on ENST00000301178 / NM_021913.5; = p.R492C on NM_001699.6) | Missense Mutation (SNP) | VAF 145/319 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771047905, COSV56563398; called by muse, mutect2, varscan2
- AXL | c.2125G>A p.A709T (on ENST00000301178 / NM_021913.5; = p.A700T on NM_001699.6) | Missense Mutation (SNP) | VAF 74/795 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1159339376, COSV56567540; called by muse, mutect2
- AZIN2 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 332/716 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs746194223, COSV53860936; called by muse, mutect2, varscan2
- AZU1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 146/296 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs1177339145; called by muse, mutect2, varscan2
- B3GALT5 | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 197/427 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.149); catalogued as rs369365169; called by muse, mutect2, varscan2
- B3GAT2 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 72/463 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as rs1181840325, COSV57770934; called by muse, mutect2, varscan2
- B3GNT3 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 157/374 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.173); catalogued as rs1351731352, COSV100592777; called by muse, mutect2, varscan2
- B3GNT3 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 48/510 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as rs1340665314, COSV57952972; called by muse, mutect2
- B3GNT4 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 219/486 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs570110830, COSV57336171; called by muse, mutect2, varscan2
- B3GNTL1 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 265/597 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs529286719; called by muse, mutect2, varscan2
- B4GALNT3 | c.2618G>T p.S873I | Missense Mutation (SNP) | VAF 53/655 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56751842; called by muse, mutect2
- B4GALNT4 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 92/261 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.182); catalogued as COSV57326114; called by muse, varscan2
- B4GALNT4 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 178/381 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.353); catalogued as COSV57327208; called by muse, varscan2
- B4GALNT4 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 211/484 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1182890681, COSV57323912; called by muse, mutect2, varscan2
- B4GALNT4 | c.2206C>T p.R736C | Missense Mutation (SNP) | VAF 138/258 reads (53%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); catalogued as COSV57324852; called by muse, varscan2
- B4GAT1 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 96/377 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.042); catalogued as COSV60819883; called by muse, varscan2
- B9D2 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 80/153 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs765309540, COSV54684892; called by muse, mutect2, varscan2
- BACE2 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 150/596 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.33); catalogued as rs541899056; called by muse, mutect2, varscan2
- BACH2 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 210/504 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57591356, COSV57611564; called by muse, mutect2, varscan2
- BAG6 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 42/684 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.437); catalogued as rs1237896711; called by muse, mutect2
- BAHCC1 | c.2194C>T p.R732W | Missense Mutation (SNP) | VAF 21/478 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781925487; called by muse, mutect2
- BAIAP3 | c.3241G>A p.E1081K | Missense Mutation (SNP) | VAF 119/241 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs567104517, COSV50104889; called by muse, mutect2, varscan2
- BANK1 | c.908G>A p.S303N | Missense Mutation (SNP) | VAF 125/216 reads (58%) | SIFT tolerated (0.33); PolyPhen benign (0.049); catalogued as rs144703386; called by muse, mutect2, varscan2
- BAP1 | c.1768C>A p.Q590K | Missense Mutation (SNP) | VAF 151/663 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as COSV56230591; called by muse, mutect2, varscan2
- BARD1 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs867639431; called by muse, mutect2
- BARHL2 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 159/358 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs751109974, COSV64982036; called by muse, mutect2, varscan2
- BASP1 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 253/563 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs1187536060; called by muse, varscan2
- BAZ1A | c.3463C>T p.R1155* | Nonsense Mutation (SNP) | VAF 23/422 reads (5%) | catalogued as rs921729277, COSV100701137; called by muse, mutect2
- BAZ2A | c.2261C>T p.S754F | Missense Mutation (SNP) | VAF 236/501 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99467270; called by muse, mutect2, varscan2
- BAZ2B | c.3025C>T p.R1009* | Nonsense Mutation (SNP) | VAF 183/482 reads (38%) | catalogued as rs761705661; called by muse, mutect2, varscan2
- BBC3 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.044); catalogued as rs755414185, COSV100340673, COSV100340855; called by muse, mutect2, varscan2
- BBS10 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 223/541 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV53887471; called by muse, mutect2, varscan2
- BBX | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 180/381 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749597573; called by muse, mutect2, varscan2
- BCAN | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 232/437 reads (53%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.64); catalogued as rs775423010; called by muse, mutect2, varscan2
- BCAR1 | c.2365G>A p.A789T | Missense Mutation (SNP) | VAF 224/506 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50785033; called by muse, mutect2, varscan2
- BCAS4 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 243/602 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs915224056, COSV52811734; called by muse, mutect2, varscan2
- BCHE | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 256/552 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV100012869, COSV99072218; called by muse, mutect2, varscan2
- BCL2L11 | c.445G>A p.A149T (on ENST00000393256 / NM_138621.5; = p.A89T on NM_006538.5) | Missense Mutation (SNP) | VAF 80/340 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1047792118, COSV58030994; called by muse, mutect2, varscan2
- BCL9 | c.1727C>T p.P576L | Missense Mutation (SNP) | VAF 191/435 reads (44%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.578); catalogued as rs781860269, COSV52342734; called by muse, mutect2, varscan2
- BCO1 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 131/486 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs746137348; called by muse, mutect2, varscan2
- BCOR | c.1374G>A p.M458I | Missense Mutation (SNP) | VAF 163/351 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs768366812, COSV60719897; called by muse, mutect2, varscan2
- BCORL1 | c.2366G>A p.R789H | Missense Mutation (SNP) | VAF 212/367 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769770475, COSV54390631, COSV54398067; called by muse, mutect2, varscan2
- BCR | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 70/279 reads (25%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs750811897, COSV100007158; called by muse, mutect2, varscan2
- BDP1 | c.3040G>A p.A1014T | Missense Mutation (SNP) | VAF 42/495 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs1387255387, COSV62432953; called by muse, mutect2
- BFSP2 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.195); catalogued as rs774937998, COSV100183488; called by muse, mutect2, varscan2
- BHLHA9 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 36/492 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs865837846; called by muse, mutect2
- BHLHE23 | c.595G>A p.A199T (on ENST00000370346; = p.A215T on NM_080606.4) | Missense Mutation (SNP) | VAF 218/511 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as rs776194669, COSV100947628; called by muse, mutect2, varscan2
- BID | c.253G>A p.A85T (on ENST00000317361 / NM_197966.2; = p.A39T on NM_001196.4) | Missense Mutation (SNP) | VAF 203/478 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs372024838; called by muse, mutect2, varscan2
- BIN1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 87/337 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as rs779607755; called by muse, mutect2, varscan2
- BIN1 | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 230/582 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV99387952; called by muse, mutect2, varscan2
- BIRC6 | c.3119C>T p.A1040V | Missense Mutation (SNP) | VAF 186/462 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746060297; called by muse, mutect2, varscan2
- BIRC6 | c.14471C>T p.A4824V | Missense Mutation (SNP) | VAF 34/626 reads (5%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.038); catalogued as rs866849386; called by muse, mutect2
- BIVM-ERCC5 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 114/457 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV57278349; called by muse, mutect2, varscan2
- BMP10 | c.665T>C p.V222A | Missense Mutation (SNP) | VAF 239/535 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV54895042; called by muse, mutect2, varscan2
- BMP2 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 207/450 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs765038230; called by muse, mutect2, varscan2
- BMP4 | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs768059149, COSV55417442; called by muse, mutect2, varscan2
- BMP4 | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 146/362 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as rs777345984, COSV99817008; called by muse, mutect2, varscan2
- BMP6 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 333/723 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as rs577694907, COSV51663347; called by muse, mutect2
- BMPER | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 195/423 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs181893738, COSV51827892; called by muse, mutect2, varscan2
- BMPR1B | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 243/513 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52775314; called by muse, mutect2, varscan2
- BNC2 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 182/378 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs1181349194; called by muse, mutect2, varscan2
- BOP1 | c.1903G>A p.V635I | Missense Mutation (SNP) | VAF 122/235 reads (52%) | SIFT tolerated (0.8); PolyPhen benign (0.009); catalogued as rs1250384349; called by muse, mutect2, varscan2
- BORA | c.457C>T p.R153C (on ENST00000613797; = p.R78C on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 248/529 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1351632765, COSV64695124; called by muse, mutect2, varscan2
- BORCS5 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 24/620 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs957497487; called by muse, mutect2
- BRAF | c.2323C>T p.R775W (on ENST00000288602 / NM_001374244.1; = p.R735W on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 209/504 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99958201; called by muse, varscan2
- BRAT1 | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 119/259 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1378548122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD3 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 184/450 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57703049; called by muse, varscan2
- BRICD5 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 118/281 reads (42%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs200895699; called by muse, mutect2, varscan2
- BRINP1 | c.2221G>A p.A741T | Missense Mutation (SNP) | VAF 269/561 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as rs768921682, COSV56293951; called by muse, mutect2, varscan2
- BRINP1 | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 164/325 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs762030572, COSV99774601; called by muse, varscan2
- BRPF1 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 159/368 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771233339; called by muse, mutect2
- BRPF1 | c.2413C>T p.R805C | Missense Mutation (SNP) | VAF 220/509 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772224645; called by muse, mutect2, varscan2
- BRPF1 | c.3170G>A p.R1057H | Missense Mutation (SNP) | VAF 178/435 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs374567525; called by muse, mutect2, varscan2
- BRWD3 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 31/716 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64748325; called by muse, mutect2
- BSN | c.1388C>A p.A463D | Missense Mutation (SNP) | VAF 105/226 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV56526174; called by muse, mutect2, varscan2
- BSN | c.8117C>T p.A2706V | Missense Mutation (SNP) | VAF 148/319 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs774527904; called by muse, mutect2, varscan2
- BSPRY | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 186/434 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs765358310; called by muse, mutect2, varscan2
- BTN3A2 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 180/412 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs375636866, COSV62687317; called by muse, mutect2, varscan2
- BTNL9 | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 289/661 reads (44%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as rs554626414; called by muse, mutect2, varscan2
- BTRC | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 187/375 reads (50%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.835); catalogued as rs752077302, COSV64561145; called by muse, mutect2, varscan2
- BTRC | c.1168C>T p.R390C (on ENST00000370187 / NM_033637.4; = p.R354C on NM_003939.5) | Missense Mutation (SNP) | VAF 117/299 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1390897262, COSV64579481; called by muse, mutect2, varscan2
- BUB1B | c.2995C>T p.R999W | Missense Mutation (SNP) | VAF 48/527 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); catalogued as rs201246315, COSV55011083; ClinVar: uncertain significance; called by muse, mutect2
- BUB3 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 238/556 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV64363654, COSV64363756; called by muse, mutect2, varscan2
- C10orf71 | c.2380C>T p.R794C | Missense Mutation (SNP) | VAF 40/373 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.154); catalogued as rs776521690; called by muse, mutect2, varscan2
- C10orf90 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 203/450 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1215727661, COSV99504499; called by muse, mutect2, varscan2
- C11orf24 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 39/397 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs765036505, COSV58505334; called by muse, mutect2, varscan2
- C11orf24 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 222/533 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs138994510; called by muse, mutect2, varscan2
- C11orf42 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 161/377 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs761530400, COSV56411614, COSV56414502; called by muse, mutect2, varscan2
- C16orf90 | c.115G>A p.A39T (on ENST00000399645 / NM_001353385.2; = p.A30T on NM_001080524.2) | Missense Mutation (SNP) | VAF 138/298 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs777586445, COSV68714593; called by muse, varscan2
- C17orf107 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 220/500 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.668); catalogued as rs1039173948, COSV53417149; called by muse, mutect2, varscan2
- C17orf97 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs782749502, COSV64076188; called by muse, mutect2, varscan2
- C19orf12 | c.173G>A p.G58D (on ENST00000392278 / NM_001031726.3; = p.G47D on NM_031448.6) | Missense Mutation (SNP) | VAF 144/563 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60365716; called by muse, mutect2, varscan2
- C19orf38 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.458); catalogued as rs892355355; called by muse, mutect2, varscan2
- C19orf47 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 124/256 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs766693508, COSV63510953; called by muse, mutect2, varscan2
- C19orf57 | c.1901G>A p.R634H (on ENST00000586783 / NM_001345843.1; = p.R603H on NM_024323.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 206/499 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148637767; called by muse, mutect2, varscan2
- C1QTNF5 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 258/505 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447464669; called by muse, mutect2, varscan2
- C1RL | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 134/332 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56924132; called by muse, mutect2, varscan2
- C1S | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 146/577 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0.01); catalogued as rs147341600; called by muse, mutect2, varscan2
- C1orf116 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 146/281 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs1405110909; called by muse, mutect2, varscan2
- C1orf131 | c.777T>G p.I259M | Missense Mutation (SNP) | VAF 112/315 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as COSV59643081; called by muse, mutect2, varscan2
- C1orf159 | c.884G>A p.G295D | Missense Mutation (SNP) | VAF 141/345 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.282); catalogued as rs763264039; called by muse, mutect2, varscan2
- C1orf198 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 240/578 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs753381372; called by muse, varscan2
- C1orf52 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 55/323 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.724); catalogued as rs780128542; called by muse, mutect2, varscan2
- C1orf74 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 215/459 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs145007795; called by muse, mutect2, varscan2
- C1orf94 | c.1469C>T p.A490V (on ENST00000488417 / NM_001134734.2; = p.A300V on NM_032884.5) | Missense Mutation (SNP) | VAF 169/353 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as rs760165855, COSV64915426; called by muse, mutect2, varscan2
- C2 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 46/880 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV54962184; called by muse, mutect2
- C2CD2L | c.581A>G p.N194S | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV60883919; called by muse, mutect2
- C2CD4A | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 66/314 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs1284655906, COSV62789095; called by muse, mutect2, varscan2
- C2orf16 | c.5156G>A p.R1719H | Missense Mutation (SNP) | VAF 188/542 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs551032627, COSV62678133; called by muse, varscan2
- C2orf50 | c.16A>G p.T6A | Missense Mutation (SNP) | VAF 42/426 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV67510574; called by muse, varscan2
- C2orf50 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 251/502 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1453975148; called by muse, mutect2, varscan2
- C3orf52 | c.579G>T p.Q193H | Missense Mutation (SNP) | VAF 90/345 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53495765; called by muse, mutect2, varscan2
- C4orf45 | c.341G>T p.R114I | Missense Mutation (SNP) | VAF 121/274 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101465093; called by mutect2, varscan2
- C7 | c.2464G>A p.A822T | Missense Mutation (SNP) | VAF 51/428 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs780107037, COSV57474906; called by muse, mutect2, varscan2
- C8orf74 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 161/367 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747337266, COSV58753666, COSV58754180; called by muse, mutect2, varscan2
- CA8 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 213/485 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.371); catalogued as rs142471870; called by muse, mutect2, varscan2
- CABIN1 | c.4811G>A p.R1604H | Missense Mutation (SNP) | VAF 326/732 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1435609117, COSV54086837; called by muse, mutect2, varscan2
- CABP4 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 244/477 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1031406409, COSV56887942; called by muse, mutect2, varscan2
- CABP4 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 170/391 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.183); catalogued as rs769011802, COSV57798807; called by muse, mutect2, varscan2
- CABP7 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 64/882 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.998); catalogued as rs200183587, COSV53363612; called by muse, mutect2
- CABS1 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 230/484 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as COSV56733301; called by muse, varscan2
- CACNA1A | c.3062C>T p.A1021V | Missense Mutation (SNP) | VAF 66/222 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1219856336, COSV64201349; called by muse, mutect2
- CACNA1A | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 256/584 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1282985383, COSV64211993; called by muse, mutect2, varscan2
- CACNA1A | c.1060C>A p.L354I | Missense Mutation (SNP) | VAF 129/515 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV100802407; called by muse, mutect2, varscan2
- CACNA1B | c.4336G>A p.A1446T | Missense Mutation (SNP) | VAF 179/567 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as rs200865012; called by muse, mutect2, varscan2
- CACNA1C | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 169/388 reads (44%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.122); catalogued as rs369483452; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1D | c.3973C>T p.R1325* (on ENST00000350061 / NM_001128840.3; = p.R1345* on NM_000720.4) | Nonsense Mutation (SNP) | VAF 259/609 reads (43%) | catalogued as COSV55436819; called by muse, mutect2, varscan2
- CACNA1F | c.4846G>A p.A1616T | Missense Mutation (SNP) | VAF 203/517 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs377551754, COSV59906862; called by muse, mutect2, varscan2
- CACNA1H | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 176/437 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1215234570; called by muse, mutect2, varscan2
- CACNA1H | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs752986607, COSV61993654; called by muse, mutect2, varscan2
- CACNA1S | c.2381G>A p.R794H | Missense Mutation (SNP) | VAF 76/772 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs760674518; ClinVar: uncertain significance; called by muse, mutect2
- CACNA2D3 | c.2320G>A p.A774T | Missense Mutation (SNP) | VAF 333/785 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as rs775275975, COSV55510818; called by muse, mutect2, varscan2
- CACNB1 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 232/470 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs763467795; called by muse, mutect2, varscan2
- CACNB2 | c.989G>A p.R330H (on ENST00000324631 / NM_201596.3; = p.R275H on NM_000724.4) | Missense Mutation (SNP) | VAF 42/742 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56622834; called by muse, mutect2
- CACNG2 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 339/711 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs1442948512; called by muse, mutect2, varscan2
- CACNG6 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as rs1310006128; called by muse, mutect2
- CACTIN | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 120/251 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV50275135; called by muse, mutect2, varscan2
- CAD | c.3448G>A p.A1150T | Missense Mutation (SNP) | VAF 198/481 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV53025216; called by muse, mutect2, varscan2
- CAD | c.4241G>A p.R1414H | Missense Mutation (SNP) | VAF 399/838 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV53033680; called by muse, mutect2, varscan2
- CADM3 | c.704C>T p.A235V (on ENST00000368125 / NM_001127173.3; = p.A269V on NM_021189.5) | Missense Mutation (SNP) | VAF 145/338 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs778876352, COSV63686096; called by muse, mutect2, varscan2
- CALML5 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 246/565 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as rs760863630, COSV66702401; called by muse, mutect2, varscan2
- CALN1 | c.586G>A p.A196T (on ENST00000329008 / NM_001017440.3; = p.A238T on NM_031468.4) | Missense Mutation (SNP) | VAF 260/630 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770151080, COSV61117552; called by muse, mutect2, varscan2
- CAMK1 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 158/342 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.059); catalogued as rs139097636, COSV56538949; called by muse, varscan2
- CAMKK2 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 98/214 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs200809684; called by muse, mutect2, varscan2
- CAMKMT | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 96/259 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1020249685, COSV65923997; called by muse, mutect2, varscan2
- CAMKV | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 198/432 reads (46%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV99615659; called by muse, mutect2, varscan2
- CAMSAP2 | c.3715C>T p.R1239W (on ENST00000236925 / NM_001297707.2; = p.R1228W on NM_203459.3) | Missense Mutation (SNP) | VAF 242/593 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199622691, COSV52667532; called by muse, mutect2, varscan2
- CAMSAP3 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 239/493 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1223754339; called by muse, mutect2, varscan2
- CAPG | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 238/528 reads (45%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs142150224; called by muse, mutect2, varscan2
- CAPN12 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 156/371 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746931323, COSV61018041; called by muse, mutect2, varscan2
- CAPN13 | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 200/469 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.704); catalogued as rs768367872, COSV54430762; called by muse, mutect2, varscan2
- CAPN15 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 40/485 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs752712228; called by muse, mutect2
- CAPN2 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 167/412 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs139659399; called by muse, mutect2, varscan2
- CAPN3 | c.2442G>A p.W814* | Nonsense Mutation (SNP) | VAF 96/346 reads (28%) | catalogued as CM080125; called by muse, mutect2, varscan2
- CAPNS1 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 92/217 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs866083785; called by muse, mutect2, varscan2
- CAPNS1 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 79/335 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs772620435; called by muse, mutect2, varscan2
- CAPNS2 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 238/528 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775683433; called by muse, mutect2, varscan2
- CAPZA2 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 188/528 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs773372818, COSV63266953; called by muse, mutect2, varscan2
- CARD10 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 359/862 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs184229951; called by muse, mutect2, varscan2
- CARD14 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 330/850 reads (39%) | catalogued as rs764656786, COSV100712617; called by muse, mutect2
- CARD8 | c.1073G>A p.R358H (on ENST00000651546 / NM_001184900.3; = p.R308H on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/690 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1490315839, COSV62873733; called by muse, mutect2
- CARD9 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 219/536 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as rs374091388; ClinVar: uncertain significance; called by muse, varscan2
- CARS2 | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 320/718 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150780076; called by muse, mutect2, varscan2
- CASKIN1 | c.4148C>T p.A1383V | Missense Mutation (SNP) | VAF 168/367 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748621679; called by muse, mutect2, varscan2
- CASP12 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 61/404 reads (15%) | catalogued as rs746375604, COSV65259724; called by muse, mutect2, varscan2
- CASP7 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 85/439 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.282); catalogued as rs1482095638, COSV61881393; called by muse, varscan2
- CASZ1 | c.4672G>A p.A1558T | Missense Mutation (SNP) | VAF 187/461 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.379); catalogued as rs760174926, COSV65456220; called by muse, mutect2, varscan2
- CAT | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 237/485 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as rs750480793, COSV53812498; called by muse, mutect2, varscan2
- CATSPER2 | c.319+2T>C p.X107_splice | Splice Site (SNP) | VAF 110/265 reads (42%) | catalogued as COSV100390627; called by muse, mutect2, varscan2
- CATSPER2 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 206/377 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs371412947; called by muse, varscan2
- CATSPERB | c.629G>A p.G210D | Missense Mutation (SNP) | VAF 240/522 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753901176; called by muse, mutect2, varscan2
- CBFA2T3 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 194/772 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as rs766793137; called by muse, mutect2, varscan2
- CBLIF | c.732G>A p.W244* | Nonsense Mutation (SNP) | VAF 50/540 reads (9%) | catalogued as COSV57240646; called by muse, mutect2
- CBS | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 34/488 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as rs761647392, CM950211; called by muse, mutect2
- CBX4 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 188/424 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs762486081, COSV53967958; called by muse, varscan2
- CBY2 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 44/421 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.555); catalogued as rs1371744667, COSV100137492; called by muse, mutect2, varscan2
- CC2D1A | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs767180596, COSV58782312; called by muse, mutect2, varscan2
- CCAR2 | c.2288G>A p.R763H | Missense Mutation (SNP) | VAF 156/399 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs201097172; called by muse, mutect2, varscan2
- CCAR2 | c.2659C>T p.R887W | Missense Mutation (SNP) | VAF 279/597 reads (47%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1304797376, COSV99374028; called by muse, mutect2, varscan2
- CCDC120 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 152/629 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs782426708; called by muse, varscan2
- CCDC134 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 134/361 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.884); catalogued as rs139931518; called by muse, mutect2, varscan2
- CCDC150 | c.2407C>T p.R803* | Nonsense Mutation (SNP) | VAF 237/551 reads (43%) | catalogued as rs1391938379, COSV55874072; called by muse, mutect2, varscan2
- CCDC151 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 220/504 reads (44%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.736); catalogued as rs368057071; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC171 | c.3316C>T p.R1106C | Missense Mutation (SNP) | VAF 240/581 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs548583619, COSV52644734; called by muse, mutect2, varscan2
- CCDC175 | c.2266C>T p.R756C | Missense Mutation (SNP) | VAF 195/432 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs369154209; called by muse, mutect2, varscan2
- CCDC175 | c.1763-1G>A p.X588_splice | Splice Site (SNP) | VAF 43/150 reads (29%) | catalogued as rs188721361; called by muse, mutect2
- CCDC177 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 116/330 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs1004160214; called by muse, mutect2
- CCDC185 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 262/550 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64820182; called by muse, mutect2, varscan2
- CCDC187 | c.2588G>A p.R863H (on ENST00000638797 / NM_001378188.1; = p.R765H on NM_001291516.1) | Missense Mutation (SNP) | VAF 267/652 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as rs1489006780; called by muse, mutect2, varscan2
- CCDC197 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 51/346 reads (15%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.82); catalogued as COSV100113697; called by muse, mutect2, varscan2
- CCDC22 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 90/338 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66051789; called by muse, mutect2, varscan2
- CCDC27 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 272/580 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs765415352, COSV53900576; called by muse, mutect2, varscan2
- CCDC34 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 263/531 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1273782378, COSV58725275; called by muse, mutect2, varscan2
- CCDC38 | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 138/313 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs142050445; called by muse, mutect2, varscan2
- CCDC51 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 212/225 reads (94%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs930556681; called by muse, mutect2, varscan2
- CCDC6 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 272/634 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1256572017, COSV54058541; called by muse, mutect2, varscan2
- CCDC71 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 200/462 reads (43%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.602); catalogued as rs1014856859, COSV58910657; called by muse, varscan2
- CCDC71 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 267/545 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs558753429; called by muse, mutect2, varscan2
- CCDC8 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 58/243 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs1380158611, COSV100282195; called by muse, mutect2, varscan2
- CCDC83 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs775185124; called by muse, mutect2, varscan2
- CCDC87 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 88/350 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs770071878; called by muse, mutect2, varscan2
- CCDC88A | c.5075A>C p.K1692T (on ENST00000436346 / NM_001365480.1; = p.K1664T on NM_018084.5) | Missense Mutation (SNP) | VAF 71/398 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99711316; called by muse, mutect2, varscan2
- CCDC93 | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 190/463 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs1319780623; called by muse, varscan2
- CCDC93 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 147/569 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs151101188; called by muse, mutect2, varscan2
- CCM2 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 90/521 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs756126156, COSV99348193; called by muse, mutect2, varscan2
- CCN1 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 176/379 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs767242673; called by muse, mutect2, varscan2
- CCN3 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 158/573 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as rs773316453, COSV52383676; called by muse, mutect2, varscan2
- CCNJ | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 196/420 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs1277109028, COSV56441699; called by muse, mutect2, varscan2
- CCNT1 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 233/480 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV99980509; called by muse, mutect2, varscan2
- CCS | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 217/582 reads (37%) | catalogued as rs745413014, COSV59579665; called by muse, mutect2, varscan2
- CCT7 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 207/473 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as rs1343594314, COSV54584219; called by muse, mutect2, varscan2
- CCT8L2 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 151/337 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as rs765930444, COSV100742876, COSV63463304; called by muse, mutect2, varscan2
- CD1A | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 205/504 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56860126; called by muse, mutect2, varscan2
- CD1D | c.534G>A p.W178* | Nonsense Mutation (SNP) | VAF 172/390 reads (44%) | catalogued as rs754401833; called by muse, varscan2
- CD207 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 68/646 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs782559266, COSV69651963; called by muse, mutect2, varscan2
- CD226 | c.928A>G p.T310A | Missense Mutation (SNP) | VAF 139/270 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1391351311; called by muse, varscan2
- CD247 | c.460G>A p.D154N (on ENST00000362089 / NM_198053.3; = p.D153N on NM_000734.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/541 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs984740029, COSV54814753, COSV54818986; called by muse, mutect2, varscan2
- CD274 | c.501G>A p.W167* | Nonsense Mutation (SNP) | VAF 137/480 reads (29%) | catalogued as COSV101056105; called by muse, mutect2, varscan2
- CD300LB | c.302T>C p.V101A | Missense Mutation (SNP) | VAF 92/463 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV58725357; called by muse, mutect2
- CD40LG | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 151/323 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs104894778, CM930085, COSV65698811; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD5 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 238/533 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs149639963; called by muse, mutect2, varscan2
- CD5 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 150/351 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs558382522, COSV100759880; called by muse, mutect2, varscan2
- CD93 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 228/525 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); catalogued as rs149969090; called by muse, mutect2, varscan2
- CDC16 | c.880T>G p.L294V | Missense Mutation (SNP) | VAF 24/295 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs754521696; called by muse, mutect2
- CDC20B | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 198/427 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1232072108, COSV99696832; called by muse, mutect2, varscan2
- CDC27 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 188/453 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50366211; called by muse, mutect2, varscan2
- CDC40 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 199/430 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.153); catalogued as COSV57009348; called by muse, mutect2, varscan2
- CDC42BPB | c.4595C>T p.A1532V | Missense Mutation (SNP) | VAF 129/282 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs202016085; called by muse, mutect2, varscan2
- CDC42BPB | c.4409-5G>A | Splice Region (SNP) | VAF 80/319 reads (25%) | catalogued as rs760136922; called by muse, mutect2, varscan2
- CDC42EP4 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 185/448 reads (41%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs372077591, COSV59964043; called by muse, mutect2, varscan2
- CDCA7L | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 89/867 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs773872806; called by muse, mutect2, varscan2
- CDCA8 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 46/505 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.38); catalogued as rs1172068276; called by muse, mutect2
- CDH1 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 302/693 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs878854694, COSV55728712; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH1 | c.2603G>A p.R868H | Missense Mutation (SNP) | VAF 249/573 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs369126891; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH22 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 268/598 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs144477780; called by muse, varscan2
- CDH23 | c.2876C>T p.A959V | Missense Mutation (SNP) | VAF 68/814 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.314); catalogued as rs779133533; ClinVar: uncertain significance; called by muse, mutect2
- CDH23 | c.6320G>A p.R2107Q | Missense Mutation (SNP) | VAF 75/584 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs780094972, COSV56460135; called by muse, mutect2, varscan2
- CDH23 | c.7880C>T p.P2627L | Missense Mutation (SNP) | VAF 137/573 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1212690615, COSV56495184, COSV99821794; called by muse, mutect2, varscan2
- CDH23 | c.9430G>A p.A3144T | Missense Mutation (SNP) | VAF 160/438 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs779358121, COSV56465682; called by muse, mutect2, varscan2
- CDH26 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 278/724 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as rs770853281, COSV54844816; called by muse, mutect2, varscan2
- CDH6 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 42/626 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV99419244; called by muse, mutect2
- CDH6 | c.2215G>A p.A739T | Missense Mutation (SNP) | VAF 216/513 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760974233, COSV54070554; called by muse, mutect2, varscan2
- CDH9 | c.1254-4C>T | Splice Region (SNP) | VAF 110/243 reads (45%) | catalogued as rs776986066; called by muse, mutect2, varscan2
- CDHR5 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 200/403 reads (50%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.708); catalogued as rs758830755; called by muse, mutect2, varscan2
- CDK11A | c.1684G>A p.G562S (on ENST00000378633 / NM_001313896.2; = p.G559S on NM_024011.4) | Missense Mutation (SNP) | VAF 144/350 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs574355501; called by muse, varscan2
- CDK16 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 144/319 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52091022; called by muse, mutect2
- CDK5RAP2 | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 173/400 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs777203757, COSV62575172; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDKAL1 | c.1622C>T p.A541V | Missense Mutation (SNP) | VAF 265/578 reads (46%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs748786790, COSV51179861; called by muse, mutect2, varscan2
- CDKN2A | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 254/587 reads (43%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs1060501274, COSV58697519; ClinVar: uncertain significance; called by muse, mutect2
- CDKN2D | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 42/455 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs577358923, COSV57264484; called by muse, mutect2
- CDON | c.1846C>T p.R616* | Nonsense Mutation (SNP) | VAF 146/299 reads (49%) | catalogued as COSV54994830, COSV54998438; called by muse, mutect2, varscan2
- CDON | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 204/440 reads (46%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as rs111947043; called by muse, mutect2, varscan2
- CDRT15L2 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 183/460 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs567353433; called by muse, mutect2, varscan2
- CDRT15L2 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 195/455 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.711); catalogued as rs1396073438, COSV67568470; called by muse, mutect2, varscan2
- CDS2 | c.1280C>T p.T427M | Missense Mutation (SNP) | VAF 276/617 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs569818585; called by muse, mutect2, varscan2
- CDT1 | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 329/750 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs143840572; ClinVar: not provided; called by muse, mutect2, varscan2
- CEBPA | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 111/527 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57196480, COSV57196783, COSV57197720; called by muse, mutect2, varscan2
- CEBPE | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 185/433 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs762247760, COSV99247651; called by muse, mutect2, varscan2
- CECR2 | c.1802G>A p.R601H (on ENST00000342247 / NM_001290047.2; = p.R418H on NM_001290046.1) | Missense Mutation (SNP) | VAF 164/392 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs565809706; called by muse, mutect2, varscan2
- CELA1 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 226/551 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as rs141584534; called by muse, mutect2, varscan2
- CELA1 | c.55G>A p.V19I | Missense Mutation (SNP) | VAF 149/380 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as rs1490458983; called by muse, mutect2, varscan2
- CELF3 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 156/680 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.667); catalogued as rs779194171, COSV51883337; called by muse, mutect2, varscan2
- CELF3 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 199/444 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs754604007, COSV99066717; called by muse, mutect2, varscan2
- CELSR1 | c.8461G>A p.A2821T | Missense Mutation (SNP) | VAF 61/867 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.859); catalogued as rs118156355; called by muse, mutect2
- CELSR1 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 113/269 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as rs761384265, COSV99419560; called by muse, mutect2, varscan2
- CELSR1 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs781549581, COSV53088510; called by muse, mutect2, varscan2
- CELSR2 | c.3047G>A p.R1016H | Missense Mutation (SNP) | VAF 270/610 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.411); catalogued as rs749457417, COSV54781056; called by muse, mutect2, varscan2
- CELSR3 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 242/560 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50850078; called by muse, mutect2, varscan2
- CENPN | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 186/629 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1482477226, COSV55142075; called by muse, mutect2, varscan2
- CEP104 | c.1213A>G p.I405V | Missense Mutation (SNP) | VAF 225/500 reads (45%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1397558523; called by muse, mutect2, varscan2
- CEP128 | c.2594G>A p.R865H | Missense Mutation (SNP) | VAF 19/362 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); catalogued as rs1166133031, COSV99824038; called by muse, mutect2
- CEP131 | c.2978G>A p.R993H (on ENST00000269392 / NM_001319228.2; = p.R990H on NM_014984.4) | Missense Mutation (SNP) | VAF 84/1072 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.399); catalogued as rs753097172; called by muse, mutect2
- CEP152 | c.1202A>G p.H401R | Missense Mutation (SNP) | VAF 160/341 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.543); catalogued as COSV57857417; called by muse, mutect2, varscan2
- CEP162 | c.2375G>A p.R792Q | Missense Mutation (SNP) | VAF 134/298 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs369357220; called by muse, varscan2
- CEP162 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 114/504 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.469); catalogued as rs148340487; called by muse, mutect2, varscan2
- CEP170B | c.1466G>A p.R489H (on ENST00000453495; = p.R418H on NM_015005.3) | Missense Mutation (SNP) | VAF 146/342 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1020511941; called by muse, mutect2, varscan2
- CEP170B | c.3377G>A p.R1126Q (on ENST00000453495; = p.R1055Q on NM_015005.3) | Missense Mutation (SNP) | VAF 167/349 reads (48%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.935); catalogued as rs759020353, COSV69023289, COSV69023358; called by muse, mutect2, varscan2
- CEP192 | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 156/350 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs752331027, COSV58064729; called by muse, mutect2, varscan2
- CEP250 | c.1468C>T p.R490* | Nonsense Mutation (SNP) | VAF 214/443 reads (48%) | catalogued as rs776554898; called by muse, mutect2, varscan2
- CEP295 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 215/521 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs953074699, COSV57350393; called by muse, mutect2, varscan2
- CEP350 | c.4873C>T p.R1625* | Nonsense Mutation (SNP) | VAF 35/564 reads (6%) | catalogued as rs1181129362, COSV62601953; called by muse, mutect2
- CEP350 | c.5605C>T p.R1869* | Nonsense Mutation (SNP) | VAF 130/585 reads (22%) | catalogued as rs1558142800; called by muse, mutect2, varscan2
- CEP44 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 98/272 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1282935113; called by muse, mutect2, varscan2
- CEP85 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 222/542 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764919627, COSV53326845; called by muse, mutect2, varscan2
- CEP85 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 250/569 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771779625; called by muse, varscan2
- CERS1 | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 336/708 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs925482243; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CES1 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 191/475 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.368); catalogued as rs772568087, COSV100828631; called by muse, mutect2, varscan2
- CES4A | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 147/338 reads (43%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs370940783; called by muse, mutect2, varscan2
- CES5A | c.352T>C p.S118P | Missense Mutation (SNP) | VAF 256/587 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99307484; called by muse, mutect2, varscan2
- CFAP43 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 209/598 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs758774398, COSV99530644; called by muse, mutect2, varscan2
- CFAP45 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 260/527 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs544005243; called by muse, mutect2, varscan2
- CFAP46 | c.2374C>T p.R792* | Nonsense Mutation (SNP) | VAF 176/411 reads (43%) | catalogued as rs762590092; called by muse, mutect2, varscan2
- CFAP46 | c.755+1G>A p.X252_splice | Splice Site (SNP) | VAF 94/440 reads (21%) | catalogued as rs1358664271, COSV100886436; called by muse, mutect2, varscan2
- CFAP52 | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 215/472 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1032552660, COSV55344830; called by muse, mutect2, varscan2
- CFAP54 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 57/630 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs981647152; called by muse, mutect2
- CFAP54 | c.5741G>T p.R1914I | Missense Mutation (SNP) | VAF 126/320 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.355); catalogued as COSV61571492; called by mutect2, varscan2
- CFAP94 | c.1292C>A p.A431D (on ENST00000320267 / NM_001352064.2; = p.A437D on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 143/367 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as COSV57231863; called by muse, mutect2, varscan2
- CFTR | c.3592G>A p.V1198M | Missense Mutation (SNP) | VAF 236/503 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.358); catalogued as rs576710089, CD941640; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHAF1A | c.821C>A p.S274Y | Missense Mutation (SNP) | VAF 24/469 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs937097472; called by muse, mutect2
- CHAT | c.1699G>A p.V567M | Missense Mutation (SNP) | VAF 252/586 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764077878, COSV60320328; called by muse, mutect2, varscan2
- CHCHD7 | c.54G>A p.S18= (on ENST00000355315 / NM_001011671.3; = p.S30= on NM_024300.4) | Splice Region (SNP) | VAF 120/528 reads (23%) | catalogued as rs768823048, COSV57614471; called by muse, varscan2
- CHD1 | c.2731C>T p.R911C | Missense Mutation (SNP) | VAF 86/200 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1209284267, COSV99399248; called by muse, mutect2, varscan2
- CHD2 | c.2647G>A p.V883I | Missense Mutation (SNP) | VAF 279/617 reads (45%) | SIFT tolerated (0.94); PolyPhen benign (0.275); catalogued as rs1289998107, COSV67714832; called by muse, mutect2, varscan2
11,100 further variants in this file (6,665 protein-altering or splice-affecting, 2,516 silent, 1,919 other) are not listed here.
